TCGA case TCGA-AG-3728 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/856a490c-c6da-48fe-88b5-9fde0f481365

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 73.7 years (26,906 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No; Residual disease: R0; Days to last follow up: 912 days (2.5 years).
   Pathology details: Circumferential resection margin: 10; Lymph nodes positive: 3; Lymph nodes tested: 19; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 61 days; Days to treatment end: 61 days; Treatment outcome: Complete Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 912.

Molecular and laboratory tests
- CEA: 1.89 ng/mL.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AG-3728-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-AG-3728-01A-01-BS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20.
  Slide TCGA-AG-3728-01A-01-TS1: Section location: Top; Percent tumor cells: 45; Percent tumor nuclei: 50; Percent normal cells: 45; Percent necrosis: 2; Percent stromal cells: 8.
- Sample TCGA-AG-3728-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-AG-3728-10A, TCGA-AG-3728-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 1.89; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Folinic acid.
- Drug treatment 2: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 912 days; disease-specific survival: no event (censored), 912 days; disease-free interval: no event (censored), 912 days; progression-free interval: no event (censored), 912 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-AG-3728-01): tumor purity 0.55, ploidy 3.02, whole-genome doublings 1 (call status: legacy_call).
